Somatic mutation profile of tumor specimen C3L-06067-54 (aliquot CPT0326980002) from CPTAC case C3L-06067, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 57.7 years (21,078 days).
Specimen C3L-06067-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 359f5113-2459-476c-ad3a-dcfc7eb074da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06067-51 (Buccal Cell Normal), aliquot CPT0327010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c53ed0c0-5aec-4110-bdb3-06e3dbbea598

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 171/333 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LSMEM2 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 62/259 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs369710882; called by muse, mutect2, varscan2
- PCDHA6 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs782446908, COSV65341958; called by muse, mutect2
- HUWE1 | c.11988C>A p.V3996= | Silent (SNP) | VAF 95/403 reads (24%) | called by muse, varscan2
- HERC2P3 | n.1503C>A | RNA (SNP) | VAF 50/1154 reads (4%) | called by muse, mutect2
